Somatic mutation profile of tumor specimen TCGA-B5-A0K3-01A (aliquot TCGA-B5-A0K3-01A-11W-A062-09) from TCGA case TCGA-B5-A0K3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 62.1 years (22,664 days).
Specimen TCGA-B5-A0K3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a81e54df-dfb1-4870-a31b-924337c79b81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0K3-10A (Blood Derived Normal), aliquot TCGA-B5-A0K3-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce6ecddd-1c4f-4f88-a383-9568b32daa0d

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 7, Splice Site 2, Frame Shift Del 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 173/258 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.532C>G p.H178D | Missense Mutation (SNP) | VAF 59/70 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795203, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACMSD | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.189); catalogued as rs779680562, COSV51607683; called by muse, mutect2, varscan2
- ADAMTS16 | c.501+2T>C p.X167_splice | Splice Site (SNP) | VAF 41/109 reads (38%) | catalogued as COSV56993478; called by muse, mutect2, varscan2
- ADCY8 | c.1496G>T p.R499M | Missense Mutation (SNP) | VAF 9/297 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV53897690, COSV53912319; called by muse, mutect2
- ARMCX5-GPRASP2 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 18/384 reads (5%) | catalogued as COSV63438221; called by muse, mutect2
- ATF3 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58378021; called by muse, mutect2, varscan2
- ATG16L2 | c.982G>C p.A328P | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as COSV58362055; called by muse, mutect2, varscan2
- ATP8B4 | c.301T>G p.F101V | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.055); catalogued as COSV52717632; called by muse, mutect2
- BMP15 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 17/386 reads (4%) | catalogued as rs782239259, COSV53140851; called by muse, mutect2
- BRCC3 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs782062912, COSV57462798; called by muse, mutect2, varscan2
- CCDC102B | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV60144962; called by muse, mutect2
- CNNM1 | c.1677G>T p.E559D | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63202085; called by muse, mutect2, varscan2
- CSPG4 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as rs571064632, COSV57896774; called by muse, mutect2, varscan2
- CYP2C8 | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 226/537 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV64877617, COSV64877953; called by muse, mutect2, varscan2
- DNAJC11 | c.359del p.Q120Rfs*14 | Frame Shift Del (DEL) | VAF 27/59 reads (46%) | catalogued as COSV53787617; called by mutect2, pindel, varscan2
- FER1L6 | c.19A>G p.K7E | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as COSV67550728, COSV67553294; called by muse, mutect2, varscan2
- FSTL5 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 6/155 reads (4%) | catalogued as COSV60201414; called by muse, mutect2
- HDX | c.22A>C p.T8P | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52978053; called by muse, mutect2
- IGHE | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1414553301; called by muse, mutect2, varscan2
- KCNA1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.099); catalogued as COSV66837783; called by muse, mutect2, varscan2
- KCNH7 | c.1267A>T p.I423L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV59800257; called by muse, mutect2, varscan2
- KIAA0753 | c.370A>G p.S124G | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV63817828; called by muse, mutect2, varscan2
- KLHL2 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56978472; called by muse, mutect2
- KRTAP13-1 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 17/374 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.054); catalogued as COSV62663594; called by muse, mutect2
- LUZP1 | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 48/606 reads (8%) | catalogued as rs1183284764, COSV56500561; called by muse, mutect2
- MARCHF7 | c.1660A>T p.I554F | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52029264; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56620872; called by muse, mutect2, varscan2
- NBEA | c.4739G>A p.R1580H | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs986998229, COSV59793708; called by muse, mutect2, varscan2
- OSBPL7 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 65/328 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs376859496, COSV99137147; called by muse, mutect2, varscan2
- PHKG1 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766046891, COSV51916853; called by muse, mutect2, varscan2
- PIK3R1 | c.1224C>A p.Y408* (on ENST00000521381 / NM_181523.3; = p.Y138* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 40/92 reads (43%) | catalogued as COSV57132059, COSV99163755; called by muse, mutect2, varscan2
- PKD1L1 | c.3303G>T p.L1101F | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV56968184; called by muse, mutect2, varscan2
- PLAGL2 | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 107/219 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.39); catalogued as rs745622775, COSV55788374, COSV99866919; called by muse, mutect2, varscan2
- PPP2R2D | c.1232A>G p.K411R | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV70779109; called by muse, mutect2
- PRMT5 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 148/348 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.137); catalogued as rs1311066310, COSV53546921; called by muse, mutect2, varscan2
- RGL2 | c.2045G>T p.R682L | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV65842409; called by muse, mutect2, varscan2
- SERINC3 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV54857264; called by muse, mutect2, varscan2
- SETBP1 | c.642C>A p.S214R | Missense Mutation (SNP) | VAF 81/373 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as COSV56325906; called by muse, mutect2
- TCN2 | c.754-2A>G p.X252_splice | Splice Site (SNP) | VAF 35/67 reads (52%) | catalogued as COSV53191822; called by muse, mutect2, varscan2
- TRIM59 | c.642T>G p.I214M | Missense Mutation (SNP) | VAF 28/351 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV59087515; called by muse, mutect2
- WDR45 | c.865C>T p.Q289* (on ENST00000376372 / NM_001029896.2; = p.Q290* on NM_007075.3) | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as CM1411578, COSV59876286; called by mutect2, varscan2
- WWC3 | c.50G>A p.W17* | Nonsense Mutation (SNP) | VAF 5/144 reads (3%) | catalogued as COSV66504152; called by muse, mutect2
- CACUL1 | c.615_616dup p.Y206Sfs*8 | Frame Shift Ins (INS) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- DOCK3 | c.2138G>A p.C713Y | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2
- ALS2 | c.1152G>A p.P384= | Silent (SNP) | VAF 69/170 reads (41%) | catalogued as rs1173868866, COSV51888386; called by muse, mutect2, varscan2
- CDSN | c.774C>T p.D258= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as rs1459164283, COSV52538648; called by muse, mutect2, varscan2
- CSMD3 | c.5793C>T p.S1931= (on ENST00000297405 / NM_001363185.1; = p.S1827= on NM_052900.3) | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV52188257, COSV52211153; called by muse, mutect2, varscan2
- CTNS | c.1083G>C p.P361= | Silent (SNP) | VAF 33/36 reads (92%) | catalogued as COSV50439843, COSV50441330; called by muse, mutect2, varscan2
- EPHB1 | c.2511C>T p.I837= | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as rs143367042, COSV67663412; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAK | c.3138G>A p.S1046= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs770478502, COSV58504211; called by muse, mutect2, varscan2
- GATA3 | c.1170G>A p.S390= | Silent (SNP) | VAF 65/149 reads (44%) | catalogued as rs150229374, COSV60520932; called by muse, mutect2, varscan2
- GLIS1 | c.81G>A p.P27= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1276215329, COSV56546666; called by muse, mutect2, varscan2
- HDAC2 | c.744G>A p.K248= | Silent (SNP) | VAF 11/196 reads (6%) | catalogued as COSV64038518; called by muse, mutect2
- PRRG1 | c.519G>A p.E173= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as COSV66157911; called by muse, mutect2, varscan2
- SNCAIP | c.1059A>G p.L353= | Silent (SNP) | VAF 75/179 reads (42%) | catalogued as COSV54412742; called by muse, mutect2, varscan2
- ZNF460 | c.807G>A p.R269= | Silent (SNP) | VAF 105/223 reads (47%) | catalogued as rs370941598; called by muse, mutect2, varscan2
- ZNF547 | c.318C>T p.D106= | Silent (SNP) | VAF 140/310 reads (45%) | catalogued as rs201774240, COSV56580879; called by muse, mutect2
- CPLANE1 | chr5:37168860 T>C | 3'Flank (SNP) | VAF 66/163 reads (40%) | catalogued as rs1191575329, COSV57063159; called by muse, varscan2
